Surgical pathology report (de-identified scan), TCGA case TCGA-60-2723, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Roswell Park, specimen TCGA-60-2723-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

SPECIMEN(S): A. 4R LYMPH NODE
B. 4R LYMPH NODE
C. 4L LYMPH NODE
D. LEVEL 7 LYMPH NODE
E. 2R LYMPH NODE
F. RIGHT MIDDLE LOBE

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Squamous cell carcinoma of right lung

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

TPA, FSA: Lymph node, 4R, excision: No malignancy identified.

TPB, TPC, FSB, FSC: Lymph nodes, 4R & 4L, respectively, excision: No malignancy identified.

TPD, TPE, FSD, FSE: Lymph nodes, 7 & 2R, respectively, excision: No malignancy identified.

[REDACTED] (A), 1:18 p.m. (B,C) and 1:28 p.m. (D, E)

FSF: Lung, right middle lobe bronchial margin, lobectomy: Bronchial margin negative for malignancy

GROSS DESCRIPTION:

A. 4R RIGHT DISTAL PARATRACHEAL LYMPH NODE

Received fresh for frozen section is a tan-pink lymph node, 0.6 x 0.4 x 0.3 cm. The specimen is bisected, touch preps are taken and the specimen is submitted entirely for frozen section in FSA1.

B. 4R RIGHT DISTAL PARATRACHEAL LYMPH NODE

[page 2 of 3]
Received fresh for frozen section is a tan-pink fatty lymph node, 0.6 x 0.4 x 0.2 cm. The specimen is bisected, touch preps are taken and the specimen is submitted entirely for frozen section in FSB1.

C. 4L LEFT DISTAL PARATRACHEAL LYMPH NODE

Received fresh for frozen section are multiple tan-pink soft tissue fragments aggregating to 0.8 x 0.4 x 0.3 cm. Touch preps are taken and the specimen is submitted entirely for frozen section in FSC1.

D. LEVEL 7 SUBCARINAL LYMPH NODE

Received fresh for frozen section are multiple tan-pink soft tissue fragments aggregating to 0.6 x 0.4 x 0.3 cm. Touch preps are taken and the specimen is submitted entirely for frozen section in FSD1.

E. 2R RIGHT PROXIMAL PARATRACHEAL LYMPH NODE

Received fresh for frozen section are multiple pieces of tan-pink soft tissue fragments, 0.6 x 0.4 x 0.3 cm. Touch preps are taken and the specimen is submitted entirely for frozen section in FSE1.

F. RIGHT MIDDLE LOBE

Received fresh is a 73 gm right lobe excision, 14 x 17 x 2.2 cm with stapled margins. The pleural surface is tan-pink, smooth and remarkable for 2 possible nodules. The bronchial margin is shaved and submitted for frozen section. The pleural surface is inked blue. The specimen is serially sectioned to reveal 2 gray-white well circumscribed nodules, 1.5 cm and 2.5 cm in greatest dimension. The smaller nodule is closest to the pleural surface at 0.1 cm and is surrounded by staples. The larger nodule measures 2.0 cm from the bronchial margin. Nodule 1 and nodule 2 measures approximately 0.8 cm away from each other. The area in between the 2 nodules is also firm, possible also involved by tumor. The remainder of the lung parenchyma is grossly unremarkable. 3 possible hilar lymph nodes are grossly identified ranging from 0.2 x 0.2 x 0.2 cm to 0.3 x 0.2 x 0.2 cm. A portion of the specimen is submitted for tissue procurement.

Representative sections are submitted as follows:

FSF1: bronchial margin submitted for frozen section

F2-F3: nodule #1 (smaller nodule)

F4: section in between nodule #1 and nodule #2

F5-F6: nodule #2

F7-F8: uninvolved lung parenchyma

F9-12: possible peri-bronchial lymph nodes

DIAGNOSIS:

A. 4R RIGHT DISTAL PARATRACHEAL LYMPH NODE, EXCISION:

- ONE LYMPH NODE, NEGATIVE FOR TUMOR.

B. 4R RIGHT DISTAL PARATRACHEAL LYMPH NODE, EXCISION:

- ONE LYMPH NODE, NEGATIVE FOR TUMOR.

C. 4L LEFT DISTAL PARATRACHEAL LYMPH NODE, EXCISION:

- ONE LYMPH NODE, NEGATIVE FOR TUMOR.

[page 3 of 3]
[REDACTED]

D. LEVEL 7 SUBCARINAL LYMPH NODE, EXCISION:

- ONE LYMPH NODE, NEGATIVE FOR TUMOR.

E. 2R RIGHT PROXIMAL PARATRACHEAL LYMPH NODE, EXCISION:

- ONE LYMPH NODE, NEGATIVE FOR TUMOR.

F. RIGHT MIDDLE LOBE, LOBECTOMY:

- SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED,
OVERALL TUMOR SIZE 4.8 CM.

- BRONCHIAL MARGIN, NEGATIVE FOR TUMOR.

- SEE NOTE AND TEMPLATE.

NOTE – Thorough examination of peri-bronchial areas failed to identify any peri-bronchial lymph nodes.

SYNOPTIC REPORT - LUNG

Specimens Involved

Specimens: F: RIGHT MIDDLE LOBE

Surgical Procedure: Lobectomy

Laterality: Right

Tumor Site: Middle lobe

Tumor Location: Peripheral

Tumor Size: Greatest diameter: 4.8cm

WHO CLASSIFICATION

Squamous cell carcinoma

Conventional type 8070/3

Histologic Grade: G2: Moderately differentiated

Angiolymphatic Invasion: Absent

Bronchial Margins: Bronchial margins uninvolved

Tumor Distance from margin: 2cm

Visceral Pleural Involvement: Absent

Satellite Tumor(s): Absent

Lymph Node Involvement: N2: Ipsilateral Mediastinal and/or Subcarinal (Levels 1-9)

Negative 0 / 4

N3: Contralateral Mediastinal/Hilar, Scalene or Supraclavicular

Negative 0 / 1

Non-Neoplastic Lung: Emphysematous changes

Additional Pathologic Findings: None identified

Pathological Staging (pTNM): pT 2 N 0 M x

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 48222359-9340-4de3-9b97-bb4b6b4b7e57 (TCGA-60-2723.681EA3DD-7685-4DC2-AA6C-73DE2AE4CC60.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).